Surgical pathology report (de-identified scan), TCGA case TCGA-X6-A8C2, project TCGA-SARC (Sarcoma), tissue source site University of Iowa, specimen TCGA-X6-A8C2-01A (Primary Tumor).

[page 1 of 2]
—SURGICAL PATHOLOGY CONSULTATION— (Accession

Status: Final result

Results

Collection Information

Specimen#	Collection Date	Collection Time	Collected By	Specimen Source	Specimen Description
-----------	-----------------	-----------------	--------------	-----------------	----------------------

Component Results

Component

DIAGNOSIS

- A. Soft tissue, superior margin, excision:
High grade pleomorphic sarcoma.
- B. Soft tissue, additional superior margin, excision:
No tumor identified.
- C. Soft tissue, additional superior margin, excision:
No tumor identified.
- D. Soft tissue, left lower extremity, resection:
High grade pleomorphic sarcoma, see comment.
Tumor size: 5.0 cm in greatest dimension.
Tumor involves the superolateral margin, and is <0.1 cm from the
margin, all other surgical margins uninvolved.
No lymphovascular or perineural invasion identified.
- E. Soft tissue, tumor superior margin, resection:
No tumor identified.

ICD O-3

Sarcoma, pleomorphic,
undifferentiated (8802/3)

Code to highest 8805/3

Date of lower limb C49.2

JAN 11/24/13

Date reported:

Pathologist (Electronic Signature)

COMMENT

The previous biopsy

was reviewed concurrently.

HISTORY

None provided.

TISSUE SUBMITTED

- A. Superior margin
- B. Additional superior margin
- C. Additional superior margin
- D. Superior margin stitch marks true margin
- E. Tumor-2 stitch inferior margin, 1 stitch marks medial, 3rd stitch
known superior margin

FROZEN SECTION

FS:

- A. Superior margin: FS: Tumor present at margin.
- B. Additional superior margin: FS: No tumor identified.
- C. Additional superior margin (#2): FS: No tumor identified.

As the frozen section pathologist on this case, I have personally reviewed and edited this portion of the case.

GROSS

- A. Received fresh are two red-brown soft tissue fragments, 0.6 to 0.7 cm in greatest dimension. A frozen section is performed and the tissue is consumed. B. Received fresh is a 2.1 x 0.8 x 0.5 cm red-brown soft tissue fragment with cautery. A frozen section is performed and the tissue is consumed. C. Received fresh is a 1.8 x 1.2 x 1.1 cm red-brown soft tissue fragment. A frozen section and the tissue is consumed.
- D. Received in formalin is a red-brown ovoid fragment of soft tissue with a small attached ellipse of skin, 7.0 cm superior to inferior, 6.1 cm medial to lateral and 8.9 cm superficial to deep. The skin ellipse is 2.1 x 1.0 cm and is unremarkable white-tan. The superficial/superior margin is inked blue, the superficial/inferior margin is inked green, the deep lateral is inked black and the deep right is inked orange. Sectioning reveals a solid soft, red-brown and focally white, well-circumscribed mass, 5.0 x 3.5 x 3.1 cm. The mass abuts the deep margin, which appears to be a fascial plane. The mass also abuts the superior and superolateral margins. The mass is 0.5 cm from the inferior and medial margins, and 0.2 cm from the superficial margin. Also there is a 1.2 x 1.2 x 0.8 cm aggregate of soft red-brown soft tissue fragments. D1, mass with superior margin; D2, mass abutting deep margin; D3, mass abutting superolateral margin and representative section of mass; D4, mass with inferior margin; D5, representative sections of separate aggregate of soft tissue.
- E. Received in formalin is a 2.2 x 1.9 x 1.0 cm ragged red tendinous soft tissue fragment with muscle. There is a stitch at one aspect designated as "sup" per specimen container. This half is inked orange, the opposite half is inked blue. Sectioning reveals unremarkable cut surfaces without masses. Entirely submitted in E1-E2.

[page 2 of 2]
MICROSCOPIC

A-C, E. Microscopic examination performed and supports the diagnosis.

D. DEFINITIONS

Pathologic Primary Tumor (T)

X T1a Superficial tumor (1)

X Regional Lymph Nodes (N)

X NX Regional lymph nodes cannot be assessed

The pathologic stage based on available pathologic material is: pT1a NX

The optimal tissue block for molecular studies on neoplasm is D2.

Performed by:

As the primary pathologist on this case, I have personally reviewed this case and edited the report as necessary.

Patient Release Status:

This result is not viewable by the patient.

Lab and Collection

---SURGICAL PATHOLOGY CONSULTATION--- (Order #

Lab and Collection Information

Result History

---SURGICAL PATHOLOGY CONSULTATION--- (Order #

Order Result History Report.

Result Entered By

Lab Information

Primary Tumor		
HPV Discrepancy		
Dual/Syncytionous Primary Noted		

10/31/13

10/30/13

Source: NCI Genomic Data Commons file ef294337-04db-4285-9bb8-be098c481694 (TCGA-X6-A8C2.F81CA9ED-6B6B-4654-A6AA-1A722D3FE71A.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).